Gene-level copy-number profile of tumor specimen TCGA-62-8394-01A from TCGA case TCGA-62-8394, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.0 years (23,758 days).
Specimen TCGA-62-8394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1389e70e-c58d-4ab1-88b8-b596616524c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-62-8394-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/70a5c51b-0719-42b3-b741-efcfe45fa1b1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,585; copy number 2: 11,281; copy number 3: 21,553; copy number 4: 16,551; copy number 5: 1,958; copy number 6: 3,790; copy number 7: 1,169; copy number 8: 44; copy number 9: 194; copy number 10: 651; copy number 12: 23; copy number 13: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-62-8394-01A-11D-2322-01): tumor purity 0.53, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,095 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:55,039,447–58,546,734, 33 genes, copy number 7–13 (within-gene range 2–13): PCSK9, USP24, MIR4422HG, GYG1P3, MIR4422, AL603840.1, GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA, LINC01755, LINC01753, PIGQP1, AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2, FYB2, AL360295.1, C8A, C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1.
- chr1:143,343,180–153,550,136, 433 genes, copy number 10 (broad region; genes not listed).
- chr1:154,944,076–155,140,595, 21 genes, copy number 9: PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3.
- chr1:187,070,700–189,133,292, 19 genes, copy number 7 (within-gene range 4–7): LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75.
- chr1:191,823,432–193,365,953, 26 genes, copy number 7 (within-gene range 3–7): LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031.
- chr1:204,131,062–205,684,307, 52 genes, copy number 8–12: AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP.
- chr5:58,198–24,271,863, 389 genes, copy number 8–10 (broad region; genes not listed).
- chr5:30,545,177–32,791,724, 43 genes, copy number 7: AC099517.1, AC026433.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3.
- chr6:60,719,222–63,779,336, 29 genes, copy number 7: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 7: AL354719.1, SCAT8, GCNT1P4.
- chr7:38,257,879–38,340,998, 14 genes, copy number 9: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 9: TRGV5P, TRGV5, TRGV4.
- chr8:107,857,589–122,127,184, 122 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:123,768,439–129,786,624, 92 genes, copy number 7 (broad region; genes not listed).
- chr8:144,148,016–144,605,816, 39 genes, copy number 7 (within-gene range 2–7): MROH1, BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39, AC084125.3.
- chr13:48,771,128–81,302,407, 370 genes, copy number 7 (broad region; genes not listed).
- chr13:84,520,103–114,337,626, 407 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,585. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
